Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A1C8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A1C8-01A (Primary Tumor).

[page 1 of 5]
100 0-3

Carcinoma, serous, NOS 8441/3

Site Code Endometrium C54.1

1/9/11 *lur*

*** FINAL REPORT ***

Provider:

Pt. Name:

Acc #:

Pt. MRN:

Col Date:

DOB/Sex:

Rec Date:

LOC:

years), Female

SURGICAL PATHOLOGY

---Pathologic Diagnosis---

A - Specimen type:

Uterus, cervix, and bilateral ovaries and fallopian tubes, resection
Papillary serous carcinoma of the endometrium
7.5 cm

Histologic type:

Tumor size:

Myometrial invasion

(no invasion, <1/2, >1/2):

<1/2

Depth of invasion (mm)

8 mm

Width of myometrium (mm)

24 mm

Myometrial lymphovascular space invasion:

Not identified

Lower uterine segment involvement:

Involved by invasive tumor

Cervical involvement:

Not involved

Cervical mucosa:

Stromal invasion

(inner 1/3, middle 1/3, outer 1/3):

Present, involving the inner 1/3, focal (A16)

Cervical lymphovascular space invasion:

Not identified

Other:

1 - Small focus of adenomyosis.

2 - Calcified uterine leiomyoma.

3 - Squamous metaplasia, tunnel clusters, and Nabothian cysts, cervix.

4 - Bilateral atrophic ovaries negative for malignancy.

5 - Bilateral fallopian tubes without histopathologic abnormality.

Pathologic Stage:

pT2b N1[IIIC] MX

B - Right periaortic lymph nodes, resection:

Three lymph nodes negative for malignancy (0/3).

C - Right pelvic lymph nodes including obturators, resection:

Eight lymph nodes negative for malignancy (0/8).

[page 2 of 5]
*** FINAL REPORT ***

Provider: Pt. Name:
Acc #: Pt. MRN:
Col Date: DOB/Sex:
Rec Date: LOC: years), Female

SURGICAL PATHOLOGY

---Pathologic Diagnosis---

A - Specimen type: Uterus, cervix, and bilateral ovaries and fallopian tubes, resection
Histologic type: Papillary serous carcinoma of the endometrium
Tumor size: 7.5 cm
Myometrial invasion
(no invasion, <1/2, >1/2): <1/2
Depth of invasion (mm) 8 mm
Width of myometrium (mm) 24 mm
Myometrial lymphovascular space invasion: Not identified
Lower uterine segment involvement: Involved by invasive tumor
Cervical involvement: Not involved
Cervical mucosa:
Stromal invasion
(inner 1/3, middle 1/3, outer 1/3): Present, involving the inner 1/3, focal (A16)
Cervical lymphovascular space invasion: Not identified
Other:
1 - Small focus of adenomyosis.
2 - Calcified uterine leiomyoma.
3 - Squamous metaplasia, tunnel clusters, and Nabothian cysts, cervix.
4 - Bilateral atrophic ovaries negative for malignancy.
5 - Bilateral fallopian tubes without histopathologic abnormality.
Pathologic Stage: pT2b N1[IIIC] MX
B - Right periaortic lymph nodes, resection:
Three lymph nodes negative for malignancy (0/3).
C - Right pelvic lymph nodes including obturators, resection:
Eight lymph nodes negative for malignancy (0/8).

[page 3 of 5]
D - Left pelvic lymph nodes including obturators, resection:
Metastatic carcinoma in one of four lymph nodes (1/4) (see Comment).

Verified by:

Pathologist
(Electronic Signature)

The attending pathologist whose signature appears on this report has reviewed all diagnostic slides and has edited the gross and/or microscopic portion of the report in rendering the final pathologic diagnosis.

---Comment---

The nodal tumor metastasis in specimen D measures approximately 0.35 cm in diameter; there is no extranodal extension.

---Microscopic Description---

Slides reviewed, microscopic description not recorded.

---Gross Description---

A - Labeled/Fixative:	Labeled with the patient's name, uterus and ovaries, fresh.
Qty/Size/Weight:	Single, 10 x 8 x 5 cm.
Tissue Description:	Specimen contains a uterus and bilateral tubes and ovaries; it has been opened for the protocol.
Endometrial tumor	
Greatest dimension:	7.5 cm.
Qualitative description:	Yellow, papillary.
Location:	Tumor grossly involves the extent of the endometrium.
Myometrial invasion	
(<1/2 or >1/2):	<1/2.
Cervical involvement:	The endocervix is velvety but there is no gross tumor involvement.
Gross lymphatic or	
vascular invasion:	Not identified.
Endometrium:	Grossly completely involved by tumor.
Myometrium:	
Lesions:	
Thickness:	One firm white nodule seen in one section measuring 0.3 x 0.3 cm.
Uterine serosa:	1.5 cm. Smooth.

[page 4 of 5]
Ovaries and fallopian tubes

Right ovary

Dimensions: 3.0 x 1.5 x 0.5 cm.
Outer surface: Yellow and cerebriform.
Cut surface: Unremarkable.

Right tube: 4.5 x 0.5 cm.

Left ovary:

Dimensions: 3.5 x 1.5 x 0.5 cm.
Outer surface: Yellow and cerebriform.
Cut surface: Unremarkable.

Left tube: 5.0 x 0.5 cm.

Sections/Processing: Representative sections are submitted as follows: (A1) anterior squamocolumnar cervix; (A2-A10) anterior endometrial/endocervical junction with the endocervical aspect inked black; (A11) posterior squamocolumnar cervix; (A12-A22) posterior endometrial/endocervical junction with the endocervical aspect inked black; (A23) right ovary and fallopian tube; (A24) left ovary and fallopian tube; (A25) representative section of tumor; (A26-A27) representative section of tumor bisected with an ink dot marking where the two sections meet (myometrial nodule in A26); (A28-A31) representative section of tumor; (A32) representative section of (A33) tissue deep to A32. (R33)

B - Labeled/Fixative: Right periaortic lymph node, pelvis, fresh.

Qty/Size/Weight: Two, in aggregate 4.5 x 1.5 x 0.5 cm.

Tissue Description: Fibrofatty tissue. Serial sectioning reveals three presumed lymph nodes.

Sections/Processing: Three presumed lymph nodes submitted in (B1). (R1)

C - Labeled/Fixative: Right pelvic lymph node including obturators, patient's name, fresh.

Qty/Size/Weight: Single, 7.0 x 3.5 x 1.0 cm.

Tissue Description: Fibrofatty tissue. Serial sectioning reveals eight presumed lymph nodes, the largest of which measures 0.8 x 0.4 x 0.3 cm.

Sections/Processing: (C1) one presumed lymph node bisected; (C2) two lymph nodes; (C3) four lymph nodes; (C4-C5) one lymph node. (R5)

D - Labeled/Fixative: Left pelvic lymph node including obturators, fresh.

Qty/Size/Weight: Two, in aggregate 6 x 4 x 1 cm.

Tissue Description: Fibrofatty tissue. Serial sectioning reveals four presumed lymph nodes.

Sections/Processing: (D1) single bisected lymph node; (D2) single

CLINICAL PATHOLOGY

bisected lymph node; (D3) two lymph nodes.
(R3)

---Clinical Information---

[page 5 of 5]
HI/PAI Discrepancy		✓

Specimen Submitted:

- A - Uterus and ovaries: Pelvis
- B - Right periaortic lymph node: Pelvis
- C - Right pelvic lymph node including obturators: Pelvis
- D - Left pelvic lymph node including obturators: Pelvis

Clinical History:

High-grade endometrial cancer, on and .

Clinical Diagnosis:

Endometrial cancer

Source: NCI Genomic Data Commons file aeefa213-54ec-4c12-a794-24909ca8d9d5 (TCGA-AX-A1C8.5F0E78BA-B827-4DB6-99EB-5FA3D3598793.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).